Somatic mutation profile of tumor specimen C3L-00893-02 (aliquot CPT0083100009) from CPTAC case C3L-00893, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 71.8 years (26,209 days).
Specimen C3L-00893-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e951b5ca-6240-4911-8cf6-9dac16c5ec0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00893-31 (Blood Derived Normal), aliquot CPT0081760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1bf3952-fc30-4441-83e1-ae265bba2b35

The open-access MAF lists 117 somatic variants for this specimen: 76 protein-altering or splice-affecting, 19 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Intron 10, 3'UTR 4, RNA 4, 5'UTR 3, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 134/617 reads (22%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANO2 | c.169G>A p.G57S (on ENST00000356134 / NM_001278597.3; = p.G61S on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs943604098, COSV59036383; called by muse, mutect2, varscan2
- ASIC1 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs766103987; called by muse, mutect2, varscan2
- CEP68 | c.2201T>C p.M734T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs752528667, COSV53124652; called by muse, mutect2, varscan2
- FAM174C | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1373884757; called by muse, mutect2, varscan2
- FLT4 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV99986903; called by muse, mutect2, varscan2
- GALNT9 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781946302, COSV61098293; called by muse, mutect2, varscan2
- HEATR6 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286279809; called by muse, mutect2, varscan2
- IGFN1 | c.3491G>A p.R1164Q (on ENST00000295591 / NM_001367841.1; = p.R3621Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs371094909; called by muse, mutect2
- IL9R | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 93/585 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1291784658; called by muse, mutect2, varscan2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2
- MSI1 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as rs1197064821; called by muse, mutect2, varscan2
- MTMR7 | c.1321T>C p.C441R | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs760519792; called by muse, mutect2, varscan2
- PIK3CD | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 156/598 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748760424, COSV63127991, COSV63130667; called by muse, mutect2, varscan2
- PPM1D | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 60/265 reads (23%) | catalogued as COSV59956007; called by muse, mutect2, varscan2
- RHEBL1 | c.32T>A p.I11N | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1027203068; called by muse, mutect2, varscan2
- RRM1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV56164206; called by muse, mutect2, varscan2
- SI | c.1509G>T p.W503C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775553090, COSV100016883; called by muse, mutect2, varscan2
- SRRM3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as rs781833246, COSV100418881; called by muse, mutect2, varscan2
- TM2D1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs751636109; called by muse, mutect2, varscan2
- ZNF354B | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs765748276, COSV59366978; called by muse, mutect2, varscan2
- ZNF641 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760568547; called by muse, mutect2
- AGTPBP1 | c.953C>T p.S318F (on ENST00000357081 / NM_001330701.2; = p.S370F on NM_001286715.1) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- ALX1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- AP5Z1 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASIC1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- AVEN | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CACNA1S | c.1602G>T p.R534S | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CBX6 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELF6 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COX10 | c.498A>T p.T166= | Splice Region (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- CRYBG1 | c.3496G>C p.E1166Q | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CYP11B2 | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 111/696 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP2C9 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 152/488 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DACH1 | c.1544G>T p.S515I (on ENST00000619232 / NM_001366712.1; = p.S463I on NM_080759.6) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH17 | c.4509C>A p.F1503L | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.10121A>T p.N3374I | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- EPHA8 | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2
- EPS8L1 | c.1945A>C p.S649R (on ENST00000201647 / NM_133180.3; = p.S522R on NM_017729.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EQTN | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM83B | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 50/582 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); called by muse, varscan2
- FRZB | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- GALNT6 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GK | c.1350A>G p.I450M (on ENST00000427190 / NM_001205019.2; = p.I444M on NM_000167.6) | Missense Mutation (SNP) | VAF 140/250 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GLS | c.1425+3_1425+5dup | Splice Region (INS) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- HADHA | c.2291G>T p.*764Lext*31 | Nonstop Mutation (SNP) | VAF 132/521 reads (25%) | called by muse, mutect2, varscan2
- HEG1 | c.2758G>T p.V920L | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- HOXA5 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.766); called by muse, mutect2
- IBSP | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MED12 | c.3637A>T p.N1213Y | Missense Mutation (SNP) | VAF 170/309 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MRPL39 | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFATC1 | c.1502C>A p.T501N | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NKX2-1 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 70/828 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2A25 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- OR2A25 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OR4K17 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, varscan2
- OR52A5 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, varscan2
- PCDHA6 | c.2319C>A p.S773R | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- POT1 | c.970T>G p.Y324D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- RAB11FIP5 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RADIL | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RIMS1 | c.1702G>T p.D568Y | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RYR2 | c.6503A>G p.H2168R | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SALL1 | c.3314C>A p.T1105N | Missense Mutation (SNP) | VAF 185/725 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIGLEC1 | c.4721C>A p.A1574D | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35F4 | c.779C>A p.T260N (on ENST00000339762 / NM_001352015.2; = p.T224N on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SPEG | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAC3 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVEP1 | c.2948A>G p.K983R | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TBCK | c.1279C>T p.P427S (on ENST00000273980 / NM_001163436.4; = p.P364S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TMC1 | c.729G>T p.L243F | Missense Mutation (SNP) | VAF 119/591 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VIRMA | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR33 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WDR81 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF304 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS16 | c.1833C>A p.R611= | Silent (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
- BOC | c.2076C>T p.P692= | Silent (SNP) | VAF 50/140 reads (36%) | called by muse, mutect2, varscan2
- CACNA1H | c.3651C>T p.R1217= | Silent (SNP) | VAF 44/454 reads (10%) | catalogued as rs929083218, COSV62004762; ClinVar: likely benign; called by muse, mutect2
- DTD1 | c.609G>T p.V203= | Silent (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- EVC | c.993G>A p.Q331= | Silent (SNP) | VAF 57/667 reads (9%) | called by muse, mutect2
- GALNT9 | c.681C>A p.R227= | Silent (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- GRIK3 | c.1938G>T p.T646= | Silent (SNP) | VAF 74/358 reads (21%) | catalogued as COSV66138584; called by muse, mutect2, varscan2
- GSTO2 | c.567G>C p.G189= | Silent (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- LZTS1 | c.546G>A p.L182= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV56115830; called by muse, mutect2, varscan2
- MUC16 | c.32433G>A p.L10811= | Silent (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.2127C>T p.L709= | Silent (SNP) | VAF 62/449 reads (14%) | catalogued as rs777670481, COSV53903519; called by muse, mutect2, varscan2
- PHOX2B | c.849C>T p.I283= | Silent (SNP) | VAF 63/272 reads (23%) | called by muse, varscan2
- PLB1 | c.708A>G p.P236= | Silent (SNP) | VAF 77/281 reads (27%) | called by muse, mutect2, varscan2
- PRCD | c.48C>A p.R16= | Silent (SNP) | VAF 68/334 reads (20%) | called by muse, mutect2, varscan2
- PTPN13 | c.6489T>C p.H2163= (on ENST00000411767 / NM_080683.3; = p.H2144= on NM_006264.3) | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- SIM2 | c.1620C>A p.P540= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- STAC3 | c.1083A>T p.L361= | Silent (SNP) | VAF 80/362 reads (22%) | called by muse, mutect2
- TMC1 | c.1936C>T p.L646= | Silent (SNP) | VAF 216/911 reads (24%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.840G>A p.V280= | Silent (SNP) | VAF 89/330 reads (27%) | catalogued as rs1261994701; called by muse, mutect2, varscan2
- AC009053.1 | n.308G>T | RNA (SNP) | VAF 112/565 reads (20%) | called by muse, varscan2
- AC009053.1 | n.307G>T | RNA (SNP) | VAF 118/576 reads (20%) | called by muse, mutect2, varscan2
- AGAP4 | c.224-10A>T | Intron (SNP) | VAF 54/207 reads (26%) | called by mutect2, varscan2
- AL645922.1 | c.256+582G>T | Intron (SNP) | VAF 71/272 reads (26%) | called by muse, mutect2, varscan2
- ALPI | c.-2A>G | 5'UTR (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- ATP1A3 | c.6+694G>A | Intron (SNP) | VAF 52/218 reads (24%) | called by muse, varscan2
- BTD | c.-293+49C>T | Intron (SNP) | VAF 19/108 reads (18%) | catalogued as rs769229686; called by muse, mutect2, varscan2
- C22orf34 | n.2121G>C | RNA (SNP) | VAF 43/155 reads (28%) | called by muse, mutect2, varscan2
- CCSER2 | c.*348_*360del | 3'UTR (DEL) | VAF 72/408 reads (18%) | called by mutect2, pindel, varscan2
- COL3A1 | c.3526-38T>C | Intron (SNP) | VAF 83/257 reads (32%) | catalogued as rs1471920459; called by muse, mutect2, varscan2
- GPATCH2L | c.984+33G>T | Intron (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- HTR1A | c.*20C>A | 3'UTR (SNP) | VAF 48/226 reads (21%) | called by muse, mutect2, varscan2
- IGSF22 | c.*455T>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, varscan2
- IQCN | c.2617-157G>T | Intron (SNP) | VAF 68/286 reads (24%) | called by muse, varscan2
- LINC01551 | n.1255-5426G>C | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs953571778; called by muse, mutect2
- OR4N3P | n.335G>T | RNA (SNP) | VAF 87/213 reads (41%) | catalogued as rs775425859; called by muse, mutect2, varscan2
- PIEZO2 | c.4633+74C>A | Intron (SNP) | VAF 73/393 reads (19%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*279G>C | 3'UTR (SNP) | VAF 56/232 reads (24%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676891 G>A | 3'Flank (SNP) | VAF 98/395 reads (25%) | called by muse, mutect2, varscan2
- RYR1 | c.-50C>T | 5'UTR (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- SFTPB | c.-20A>T | 5'UTR (SNP) | VAF 53/222 reads (24%) | called by muse, varscan2
- USP32P1 | n.334+1126G>T | Intron (SNP) | VAF 39/426 reads (9%) | called by muse, mutect2, varscan2
